Surgical pathology report (de-identified scan), TCGA case TCGA-EM-A2OZ, project TCGA-THCA (Thyroid Carcinoma), tissue source site University Health Network, specimen TCGA-EM-A2OZ-01A (Primary Tumor).

[page 1 of 3]
LABORATORY MEDICINE PROGRAM

Surgical Pathology Consultation Report

Patient
Name:
MRN:
DOB:
Gender: M
HCN:
Ordering
MD:
Copy To:

Service:
Visit #:
Location:
Facility:

Accession #:
Collected:
Received:
Reported:

Reviewed Initials: [Signature]		

Specimen(s) Received

1. Thyroid: LEFT PARATHYROID (QS)
2. Thyroid: TOTAL THYROID, STITCH MARKS UPPER POLE LEFT LOBE

Diagnosis

1. No pathological diagnosis: Parathyroid (left) biopsy.
2. Multifocal papillary carcinoma, dominant 1.7cm classical variant, isthmus; follicular nodular disease with dominant follicular adenoma 2.5 cm showing extensive degeneration and reactive atypia, left: Thyroid
No pathological diagnosis: Lymph nodes, 2, isthmus
No pathological diagnosis: Parathyroid, intrathyroidal right
-Total thyroidectomy specimen.

Synoptic Data

Procedure: Total thyroidectomy
Received: Fresh
Specimen Integrity: Intact
Specimen Size: Right lobe:
5.2 cm
2.5 cm
1.4 cm
Left lobe:
5.4 cm
3.2 cm
1.9 cm
Isthmus +/- pyramidal lobe:
3.0 cm
2.5 cm
0.9 cm

ICD-0-3
Carcinoma, papillary, thyroid.
8260/3
Site: thyroid, NOS C73.9
pw 8/24/11

[page 2 of 3]
Specimen Weight:	33.0 g
Tumor Focality:	Multifocal, bilateral Multifocal, midline (isthmus)
----- DOMINANT TUMOR -----	
Tumor Laterality:	Isthmus
Tumor Size:	Greatest dimension: 1.7cm
Histologic Type:	Papillary carcinoma, classical (usual) Classical (papillary) architecture Other architecture: focal hobnail cell change (<5%). Classical cytomorphology
Histologic Grade:	Not applicable
Margins:	Margins uninvolved by carcinoma Distance of invasive carcinoma to closest margin: 0.1mm
Tumor Capsule:	Partially encapsulated
Tumor Capsular Invasion:	Present, extent minimal
Lymph-Vascular Invasion:	Not identified
Perineural Invasion:	Not identified
Extrathyroidal Extension:	Not identified
----- SECOND TUMOR -----	
Tumor Laterality:	Left lobe
Tumor Size:	Greatest dimension: 0.6cm
Histologic Type:	Papillary carcinoma, macrofollicular variant Papillary carcinoma, microcarcinoma (occult, small or microscopic) variant Macrofollicular architecture Classical cytomorphology
Histologic Grade:	Not applicable
Margins:	Margins uninvolved by carcinoma
Tumor Capsule:	Partially encapsulated
Tumor Capsular Invasion:	Not identified
Lymph-Vascular Invasion:	Not identified
Perineural Invasion:	Not identified
Extrathyroidal Extension:	Not identified
TNM Descriptors:	m (multiple primary tumors)
Primary Tumor (pT):	pT1b: Tumor more than 1 cm but not more than 2 cm in greatest dimension, limited to the thyroid
Regional Lymph Nodes (pN):	pN0: No regional lymph node metastasis Number of regional lymph nodes examined: 2 Number of regional lymph nodes involved: 0
Distant Metastasis (pM):	Not applicable
Additional Pathologic Findings:	Adenoma Adenomatoid nodule(s) or Nodular follicular disease Parathyroid gland(s), within normal limits Other: Additional papillary microcarcinomas identified in right lobe (0.1, 0.05cm).

*Pathologic Staging is based on AJCC/UICC TNM, 7th Edition

Electronically

verified by:

[page 3 of 3]
Gross Description

1. The specimen labelled with the patient's name and as "Thyroid: Left parathyroid QS" consists of a piece of tissue that measures 0.1 cm in diameter. It is frozen for intraoperative consultation.
1A frozen section block resubmitted

2. The specimen labeled with the patient's name and as "Thyroid: Total thyroid, stitch marks upper pole left lobe" consists of a thyroid gland that is oriented with a stitch and weighs 33.0 g. The right lobe measures 5.2 cm SI x 2.5 cm ML x 1.4 cm AP, the left lobe measures 5.4 cm SI x 3.2 cm ML x 1.9 cm AP and the isthmus measures 3.0 cm SI x 2.5 cm ML x 0.9 cm AP. The external surfaces have fibrous adhesions. No parathyroid glands or lymph nodes are identified grossly. The external surface is painted with Silver nitrate. The right lower lobe contains a well delineated nodule that measures 1.5 cm SI x 0.8 cm ML x 1.0 cm AP. The isthmus contains a well delineated nodule that measures 1.7 cm SI x 1.2 cm ML x 0.9 cm AP. The left lower lobe contains a cystic lesion that measures 2.5 cm SI x 1.2 cm ML x 1.0 cm AP. The remainder of the thyroid tissue is unremarkable. Sections of each nodule and normal tissue are stored frozen. The remainder of the specimen is submitted as follows:

2A-H right lobe, superior to inferior

2I-L isthmus

2M-U left lobe, superior to inferior

Quick Section Diagnosis

1. Left parathyroid for QS: Parathyroid tissue present
Result reported at

Source: NCI Genomic Data Commons file f3c8fa32-7ffc-458d-ad69-986558575f73 (TCGA-EM-A2OZ.6BAC2A4F-D374-4F03-A25B-E73A622DB185.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).